CCDI case PBCLHP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/de698580-479a-4abd-a04f-2e7935a1a34e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 2.1 years (764 days).

Biospecimens (3 samples)
- Samples 0DUKGS, 0DUKHJ (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUKIT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
